Somatic mutation profile of tumor specimen TCGA-CN-6998-01A (aliquot TCGA-CN-6998-01A-23D-2012-08) from TCGA case TCGA-CN-6998, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.2 years (19,447 days).
Specimen TCGA-CN-6998-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0d34d3e-aee1-4c9c-8574-cc4876233fe6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6998-10A (Blood Derived Normal), aliquot TCGA-CN-6998-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ee3dbb4-8275-4d96-a83a-98fbf365481b

The open-access MAF lists 86 somatic variants for this specimen: 56 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 27, Nonsense Mutation 6, Frame Shift Ins 2, Intron 1, RNA 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 20/31 reads (65%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 51/76 reads (67%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RHOA | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 96/146 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1057519951, COSV69041613, COSV69042111, COSV69043712; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 59/92 reads (64%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AJUBA | c.1298A>T p.N433I | Missense Mutation (SNP) | VAF 60/93 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV52984352, COSV52986741; called by muse, mutect2, varscan2
- AKT2 | c.1052A>G p.Y351C | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs1020231672, COSV60908487; called by muse, mutect2, varscan2
- CDC42 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.738); catalogued as COSV59662334; called by muse, mutect2, varscan2
- CIT | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs770757019, COSV55865386, COSV55886953; called by muse, mutect2, varscan2
- CLEC2D | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV51992451, COSV51996085; called by muse, varscan2
- CNTN3 | c.2977C>T p.R993* | Nonsense Mutation (SNP) | VAF 96/170 reads (56%) | catalogued as rs757006391, COSV55162682; called by muse, mutect2, varscan2
- CRACD | c.2456C>T p.S819L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV51723578; called by muse, mutect2, varscan2
- ELMO3 | c.1085G>A p.R362Q (on ENST00000652269; = p.R309Q on NM_024712.5) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs770450376, COSV62607353; called by muse, mutect2, varscan2
- EPHA10 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100139860; called by muse, mutect2, varscan2
- EXPH5 | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.923); catalogued as COSV56198711, COSV56203600; called by muse, mutect2, varscan2
- FARSB | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs538600753, COSV99918140, COSV99918255; called by muse, varscan2
- FOSL2 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs997476425, COSV99268269; called by muse, mutect2, varscan2
- GLRA2 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs866815225, COSV99490598; called by muse, mutect2
- GRAMD1C | c.1823C>G p.S608* | Nonsense Mutation (SNP) | VAF 54/232 reads (23%) | catalogued as COSV63981718; called by muse, mutect2, varscan2
- H2AC16 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.248); catalogued as COSV58898903, COSV58899509; called by muse, mutect2, varscan2
- HECW2 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.715); catalogued as rs775078362, COSV53648600, COSV99649188; called by muse, mutect2, varscan2
- IWS1 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV54866377; called by muse, mutect2, varscan2
- KCNH1 | c.1739C>T p.P580L (on ENST00000271751 / NM_172362.3; = p.P553L on NM_002238.4) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs1205959947, COSV55086648, COSV55086749; called by muse, mutect2, varscan2
- KCNT2 | c.1500dup p.A501Cfs*2 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | catalogued as rs1249079077; called by mutect2, pindel, varscan2
- KMT2C | c.4541-1G>C p.X1514_splice | Splice Site (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100070545, COSV51405075; called by muse, mutect2, varscan2
- LCT | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1340454714, COSV51543851; called by muse, mutect2, varscan2
- MAPKAPK3 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 102/163 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63598614; called by muse, mutect2, varscan2
- MID2 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV53306617; called by muse, mutect2, varscan2
- MPP5 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 63/83 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs150659640; called by muse, mutect2, varscan2
- OPA3 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs553598004, COSV99619834; called by muse, mutect2
- OR1A2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1013049355, COSV67936073; called by muse, mutect2, varscan2
- PACS2 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as COSV57649731; called by muse, mutect2, varscan2
- PCDHGA2 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53895716; called by muse, mutect2, varscan2
- PCNX3 | c.5104C>T p.R1702C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1023840698, COSV63139381; called by muse, mutect2, varscan2
- PDE8B | c.1435C>G p.L479V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV53731787; called by muse, mutect2, varscan2
- PHF3 | c.5483T>C p.M1828T | Missense Mutation (SNP) | VAF 94/231 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV50313035; called by muse, mutect2, varscan2
- PLCB4 | c.832G>C p.D278H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV53792364; called by muse, mutect2, varscan2
- PRKAA2 | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 141/325 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV64801843; called by muse, mutect2, varscan2
- RAB43 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59349500; called by muse, mutect2, varscan2
- SAFB | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 28/58 reads (48%) | catalogued as COSV99412630; called by muse, mutect2
- SI | c.1168G>C p.D390H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100014703; called by muse, mutect2
- SKIDA1 | c.2230G>C p.E744Q | Missense Mutation (SNP) | VAF 85/245 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV101481271; called by muse, mutect2, varscan2
- SLC2A12 | c.662C>G p.P221R | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99259777; called by muse, mutect2, varscan2
- SOBP | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs372864608, COSV100433283; ClinVar: uncertain significance; called by muse, mutect2
- SORCS3 | c.2770G>A p.V924I | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.881); catalogued as COSV63793218; called by muse, mutect2, varscan2
- TCERG1 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1218620347, COSV99694598; called by muse, mutect2, varscan2
- TMEM94 | c.1357C>A p.L453I | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.277); catalogued as COSV58592844; called by muse, mutect2, varscan2
- TP53I11 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.251); catalogued as COSV100371043, COSV57532574; called by muse, mutect2, varscan2
- TP63 | c.7T>C p.F3L | Missense Mutation (SNP) | VAF 84/159 reads (53%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); catalogued as COSV53195914; called by muse, mutect2, varscan2
- TRPM6 | c.3460G>A p.V1154M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs371962660; called by muse, mutect2, varscan2
- TSC22D4 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV100278843; called by muse, mutect2, varscan2
- USP26 | c.1150C>G p.H384D | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100896585, COSV63709074; called by muse, mutect2, varscan2
- VPS25 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141909224; called by muse, mutect2, varscan2
- ZFHX4 | c.2260G>A p.G754R | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs771826272, COSV50482685, COSV99257354; called by muse, mutect2, varscan2
- ZNF251 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 110/249 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs200948268, COSV52955805, COSV99035065; called by muse, varscan2
- FRG2 | c.338G>C p.C113S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- STK25 | c.861dup p.K288* | Frame Shift Ins (INS) | VAF 22/127 reads (17%) | called by mutect2, pindel, varscan2
- AFM | c.406C>T p.L136= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs770032414, COSV56921777; called by muse, mutect2, varscan2
- AL031777.2 | c.24C>T p.G8= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs748398521, COSV100587142; called by muse, mutect2, varscan2
- ANO4 | c.1965G>T p.V655= (on ENST00000392977 / NM_001286615.2; = p.V620= on NM_178826.4) | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV54584659; called by muse, mutect2, varscan2
- ASTN1 | c.3780C>T p.P1260= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as COSV62490539; called by muse, mutect2, varscan2
- BCAN | c.2574C>T p.C858= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as COSV100227959; called by muse, mutect2, varscan2
- CCDC66 | c.2304G>A p.T768= (on ENST00000394672 / NM_001353147.1; = p.T734= on NM_001012506.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs749970753, COSV100413820, COSV100414109; called by muse, varscan2
- CNGB3 | c.1515G>A p.T505= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs751667290, COSV60684314; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPVL | c.888C>T p.G296= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs370525550, COSV55298929, COSV55301485; called by muse, varscan2
- DDI2 | c.288C>T p.F96= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as rs948393633, COSV60779369; called by muse, mutect2, varscan2
- DMD | c.1677C>G p.L559= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV55852791, COSV55869196; called by muse, mutect2, varscan2
- ENPEP | c.144C>T p.D48= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as rs778573747, COSV54448335; called by muse, mutect2, varscan2
- ERMARD | c.349C>T p.L117= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs1393372924, COSV64649292; called by muse, mutect2, varscan2
- GAB2 | c.1065C>T p.P355= (on ENST00000361507 / NM_080491.3; = p.P317= on NM_012296.3) | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV60865926; called by muse, mutect2, varscan2
- GLIS1 | c.1862G>A p.*621= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100389685; called by muse, mutect2, varscan2
- MAP1B | c.5190G>A p.P1730= | Silent (SNP) | VAF 88/218 reads (40%) | catalogued as rs758570511, COSV57093543; called by muse, mutect2, varscan2
- MB21D2 | c.997C>A p.R333= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV101165064; called by muse, mutect2, varscan2
- MPO | c.1341G>A p.R447= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV56561087; called by muse, mutect2, varscan2
- MYO15A | c.600C>T p.G200= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs760331617, COSV99231846; called by muse, mutect2, varscan2
- MYRF | c.195G>A p.A65= (on ENST00000278836 / NM_001127392.3; = p.A56= on NM_013279.4) | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1310326234, COSV99606781; called by muse, mutect2, varscan2
- NEU2 | c.732C>T p.V244= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV99290502; called by muse, mutect2, varscan2
- PCDHB4 | c.1545C>T p.L515= | Silent (SNP) | VAF 68/363 reads (19%) | catalogued as COSV99521995; called by muse, mutect2, varscan2
- SALL1 | c.1365G>A p.A455= | Silent (SNP) | VAF 49/112 reads (44%) | catalogued as rs371503908; called by muse, mutect2, varscan2
- SIGLEC10 | c.2093G>A p.*698= | Silent (SNP) | VAF 69/109 reads (63%) | catalogued as rs774632621, COSV59478589; called by muse, mutect2, varscan2
- SUSD5 | c.990C>T p.V330= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as rs1386118190, COSV100535020; called by muse, mutect2, varscan2
- TAF4 | c.1803T>A p.S601= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV53334257; called by muse, varscan2
- TRIP13 | c.825C>T p.R275= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as rs146441673; called by muse, mutect2, varscan2
- UNC79 | c.4647A>G p.R1549= (on ENST00000393151 / NM_001346218.2; = p.R1372= on NM_020818.5) | Silent (SNP) | VAF 69/104 reads (66%) | catalogued as COSV56372859; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498138 G>C | 5'Flank (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- MAST2 | c.500+35047G>A | Intron (SNP) | VAF 46/96 reads (48%) | called by muse, mutect2, varscan2
- SSPOP | n.4562C>T | RNA (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100022277; called by muse, mutect2, varscan2
